Surgical pathology report (de-identified scan), TCGA case TCGA-3X-AAVB, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Alberta Health Services, specimen TCGA-3X-AAVB-01A (Primary Tumor).

[page 1 of 4]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected		Time Received	
Time Reported		Time Transmitted	
Order Number		Ordering Provider	
Status	Final	Relevant Information	
		Location	

Copied To

Report Patient Name:
Demographics (for verification purposes) Date of Birth:
Sex: F

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description

- A. Lymph node #8 at
- B. Gallbladder at
- C. Portal lymph node at
- D. Pancreatic duct margin at
- E. Whipple specimen at

Clinical Information

Pancreatic cancer.
Infectious patient: No
Immunocompromised: Yes
History of neoplasm: Yes

CHIEF *ICD O-3*
Cholangiocarcinoma 8160/3
path Adenocarcinoma NOS 8140/3
Site: Bile duct, intrahepatic C24.0
Op 5/21/14

Diagnosis

- A. Lymph Node # 8:
- One reactive lymph node, negative for malignancy.
- B. Gallbladder:
- Unremarkable gallbladder.
- Negative for malignancy or dysplasia.
- C. Portal Lymph Node:
- One reactive lymph node, negative for malignancy.
- D. Pancreatic Duct Margin:
- Negative for malignancy.
- E. Pancreas and Duodenum, Partial Pancreaticoduodenectomy:
- Invasive moderately differentiated adenocarcinoma with mucinous features in the periaampullary region, most consistent with biliary (common bile duct) origin.
- Tumor invaded into pancreas and periaampullary duodenal wall

[page 2 of 4]
- (muscle layer only).
- Tumor invaded into peripancreatic fat.
- Positive for perineural invasion.
- Positive for lymphatic channel invasion.
- PanIN 2 and 3.
- Resection margins free of tumor: 0.2 cm from vascular bed margin, 0.4 cm from the outer surface of the peripancreatic fat, 0.2 cm from uncinate margin, and 0.7 cm from pancreatic distal transection margin.
-
- One incidental pancreatic well differentiated neuroendocrine tumor (0.15 cm) in the midst of infiltrating adenocarcinoma.
- 5 of 15 peripancreatic /biliary lymph nodes positive for metastatic carcinoma.
- See Synoptic report and Comment.

Reported by:

Electronically signed by:

Verified:

Synoptic Report

E: Extrahepatic Bile Ducts, Macroscopic

SPECIMEN:

Common bile duct

OTHER ORGANS RECEIVED:

Duodenum

Pancreas

Ampulla

Gallbladder

PROCEDURE:

Pancreaticoduodenectomy

TUMOR SITE:

Common bile duct

Extrapancreatic

Intrapancreatic

TUMOR SIZE:

Greatest dimension: 2.5 cm

E: Extrahepatic Bile Ducts, Microscopic

HISTOLOGIC TYPE:

Adenocarcinoma (not otherwise characterized)

HISTOLOGIC GRADE:

G2: Moderately differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades beyond the wall of the bile duct

Tumor invades the duodenum

Tumor invades the pancreas

MARGINS: SEGMENTAL RESECTION SPECIMEN

MARGINS: PANCREATICODUODENAL RESECTION SPECIMEN:

Uninvolved by invasive carcinoma

Uninvolved by invasive carcinoma

Uninvolved by invasive carcinoma

Margin uninvolved by invasive carcinoma

Margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 0.2 cm

Specified margin: Uncinate

LYMPHATIC (SMALL VESSEL) INVASION (L):

Present

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

[page 3 of 4]
pT3: Tumor invades the gallbladder, pancreas, duodenum, or other adjacent organs without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

DISTANT METASTASIS (pM):

Not applicable

Gross Description

Received are specimen containers A to E. All requisitions and specimen containers are labelled with the patient's name, The cassettes and identifiers are labelled with the Surgical Number

A The specimen is received in formalin and designated as "lymph node #8". The specimen consists of one piece of fibroadipose tissue measuring 1.4 x 1.2 x 0.4 cm. One lymph node is retrieved, 1.1 cm in greatest dimension. The specimen is submitted entirely in one cassette.

B. The specimen is received fresh and is subsequently placed into formalin, designated as "gallbladder". The specimen consists of an intact cholecystectomy specimen. The gallbladder measures 9.0 x 4.0 x 3.0 cm. The serosal surface is smooth. The cystic duct is patent. No gallstones are identified. The cystic mucosa is smooth and velvety with no obvious lesions identified. Representative sections are submitted in one cassette.

C. The specimen is received fresh and designated as "portal lymph node". The specimen consists of one piece of lymph node measuring 1.3 cm in greatest dimension. The lymph node is bisected and submitted in two cassettes.

D. The specimen consists of a piece of pancreatic tissue which measures 1.2 x 0.7 cm. All tissue submitted for QS in one block.

E. The specimen is designated as "Whipple specimen". The specimen consists of a partial pancreaticoduodenal resection specimen including a segment of duodenum 22.0 cm in length and 5.4 cm in maximum circumference, and portion of pancreatic head attached. The portion of pancreas measures 3.5 x 3.5 x 3.3 cm. A portion of common bile duct is identified, 2.8 cm in length and 1.5 cm in the circumference at the proximal resection margin. The distal portion of the common bile duct appears to be compressed by the surrounding structure. The ampullary region is prominent. The rest of the duodenal mucosa appears unremarkable. The resection margin of pancreas is inked blue, the vascular bed inked green, and margin of uncinata inked in orange. Serial cross sections through the pancreas reveal an ill-defined firm mass lesion, 2.5 cm in greatest dimension. On cut surface, the pancreatic mass appears homogenous and whitish with no necrosis, hemorrhage or cystic changes. The tissue around the common bile duct appears to be fibrotic and involved by tumor. Grossly, the tumor is 0.7 cm from the closest resection margin of pancreas, approximately 0.1 cm from the vascular bed margin, and 0.2 cm from the uncinata margin.

Representative sections are submitted in cassettes labelled as follows:

- E1. proximal margin of duodenum
- E2. distal margin of duodenum
- E3. shaved proximal margin of common bile duct
- E4. cross section of common bile duct next to shaved margin with vascular bed margin
- E5-6. single cross section next to E4 with E6 including uncinata margin
- E7. peripancreatic fat and lymph node next to E6
- E8. cross section through common bile duct and surrounding tissue, next to E5 and E6
- E9. cross section through distal common bile duct and surrounding tissue, next to E8
- E10-11. single cross section, including uncinata margin, vascular bed margin and

[page 4 of 4]
pancreatic

- resection margin
- E12-13. single cross section through the pancreatic mass and ampulla
- E14-16. single cross section through the pancreatic tumor and ampullary region
- E17. cross section through ampullary region and underlying mass
- E18. tumor with uncinate margin
- E19. resection margin of pancreas
- E20. tumor with uncinate margin
- E21. pancreatic resection margin
- E22-23. tumor with resection margin
- E24. peripancreatic fat with nodule under serosal surface
- E25. peripancreatic lymph nodes

Frozen Section Diagnosis

- D. Pancreatic Duct Margin:
- Negative for malignancy.

Reported by:

Pathologist Comment

The carcinoma is mostly invaded around the common bile duct and involves the bile ductal mucosa. Based on the microscopic findings, this tumor is considered biliary primary, although panIN is present.

The incidental neuroendocrine tumor is confirmed by its strong immunopositivity for synaptophysin and chromogranin, while the surrounding adenocarcinoma is negative.

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file 91b2ab32-4359-44a4-b7e2-aab9ae79652c (TCGA-3X-AAVB.BEA4C577-73ED-48F0-9417-AA8BD143B5C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).